Somatic mutation profile of tumor specimen MP2PRT-PAUAYD-TMP1-A (aliquot MP2PRT-PAUAYD-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUAYD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,634 days).
Specimen MP2PRT-PAUAYD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fefeffc6-4a50-42c5-8d57-a88a04d38e7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUAYD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUAYD-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04c10f4f-59e1-4995-b24b-0dc53a36e4d5

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Nonsense Mutation 4, Silent 4, Frame Shift Ins 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 63/256 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APRT | c.270dup p.K91Efs*19 | Frame Shift Ins (INS) | VAF 110/448 reads (25%) | catalogued as rs761430319; called by mutect2, pindel, varscan2
- ATP1A4 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs141465620, COSV100927661; called by muse, mutect2, varscan2
- CLSTN1 | c.2815G>A p.G939S (on ENST00000377298 / NM_001009566.3; = p.G929S on NM_014944.4) | Missense Mutation (SNP) | VAF 192/492 reads (39%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as rs768841934; called by muse, varscan2
- EPHB4 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 26/576 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1222689023, COSV100639533; called by muse, mutect2
- FLNB | c.7123G>A p.V2375I | Missense Mutation (SNP) | VAF 121/354 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs767864936, COSV99915675; called by muse, mutect2, varscan2
- LHX3 | c.94G>A p.A32T (on ENST00000371748 / NM_178138.6; = p.A37T on NM_014564.5) | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as rs201187873, COSV65582566; called by muse, mutect2, varscan2
- METTL3 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs1003797027; called by muse, mutect2
- NALCN | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as COSV99058580; called by muse, mutect2
- PEAR1 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 11/393 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430734074, COSV52774443; called by muse, mutect2
- TNXB | c.9841G>A p.A3281T (on ENST00000647633; = p.A3034T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs770049252; called by muse, varscan2
- AHNAK2 | c.1292_1293insCTG p.T431_A432ins* | Nonsense Mutation (INS) | VAF 138/407 reads (34%) | called by mutect2, pindel, varscan2
- COL14A1 | c.4498C>T p.Q1500* | Nonsense Mutation (SNP) | VAF 10/274 reads (4%) | called by muse, mutect2
- IGKV1D-16 | chr2:90100738 TCCCACAGTGTTACACACCCAAACAT>CCG | Missense Mutation (DEL) | VAF 65/202 reads (32%) | called by pindel, varscan2*
- KIAA1958 | c.2061G>T p.K687N | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); called by muse, mutect2
- KIF2C | c.1193_1202dup p.F401Lfs*14 | Frame Shift Ins (INS) | VAF 53/152 reads (35%) | called by mutect2, varscan2
- MAP3K15 | c.2259C>A p.Y753* | Nonsense Mutation (SNP) | VAF 55/233 reads (24%) | called by muse, mutect2, varscan2
- OFD1 | c.1274_1280delinsCCCCA p.H425Pfs*4 | Frame Shift Del (DEL) | VAF 41/187 reads (22%) | called by pindel, varscan2*
- TMEM212 | c.56G>C p.S19T | Missense Mutation (SNP) | VAF 76/316 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBE3C | c.2830G>A p.A944T | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- UBR4 | c.8161C>T p.R2721* | Nonsense Mutation (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- WDR64 | c.593A>T p.Q198L | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- IRS4 | c.297A>G p.K99= | Silent (SNP) | VAF 22/816 reads (3%) | called by muse, mutect2
- LAMB3 | c.3318G>A p.Q1106= | Silent (SNP) | VAF 79/501 reads (16%) | called by muse, mutect2, varscan2
- OR5M1 | c.765C>T p.L255= | Silent (SNP) | VAF 8/242 reads (3%) | catalogued as COSV101591525, COSV73202450; called by muse, mutect2
- ZBTB4 | c.1059G>A p.T353= | Silent (SNP) | VAF 15/262 reads (6%) | catalogued as rs377098416; called by muse, mutect2
- OR7E19P | n.174G>A | RNA (SNP) | VAF 78/196 reads (40%) | catalogued as rs979788704; called by muse, mutect2, varscan2
